Somatic mutation profile of tumor specimen TARGET-40-0A4HMC-01A (aliquot TARGET-40-0A4HMC-01A-01D) from TARGET case TARGET-40-0A4HMC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 27.9 years (10,205 days).
Specimen TARGET-40-0A4HMC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7213299-234e-4530-8085-7faa6068579e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HMC-10A (Blood Derived Normal), aliquot TARGET-40-0A4HMC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe0c72e5-9fd4-42db-a845-49e931b6024f

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, RNA 2, 5'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.6534G>T p.L2178F (on ENST00000394518 / NM_007200.5; = p.L2182F on NM_006738.6) | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63450592; called by muse, mutect2, varscan2
- CNOT2 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as rs373865743; called by mutect2, varscan2
- SYNPR | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs756375711; called by muse, mutect2, varscan2
- ZNF667 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV104391416; called by muse, mutect2, varscan2
- ADAM7 | c.1995T>A p.H665Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNRNPUL1 | c.849_850insCG p.I284Rfs*13 | Frame Shift Ins (INS) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.1783A>G p.T595A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NPVF | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- PCNT | c.2906A>T p.D969V | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RAMP2 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNHD1 | c.13081C>T p.L4361= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- KANK1 | c.42A>G p.K14= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- KLHL20 | c.27T>C p.C9= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs745885634; called by muse, mutect2, varscan2
- MAP4 | c.2364A>C p.P788= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs373873361; called by muse, mutect2
- AC010655.3 | n.51C>G | RNA (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- BX664615.1 | n.358_360delinsCTGTGCGCTGAGGCTCTAAGG | RNA (INS) | VAF 9/50 reads (18%) | called by pindel, varscan2*
- CCDC150 | c.1866+624C>G | Intron (SNP) | VAF 8/31 reads (26%) | catalogued as COSV55872405; called by muse, mutect2, varscan2
- LRRTM4 | c.-7A>G | 5'UTR (SNP) | VAF 22/103 reads (21%) | catalogued as COSV101297393; called by muse, mutect2, varscan2
